Surgical pathology report (de-identified scan), TCGA case TCGA-AC-A2FK, project TCGA-BRCA (Breast Invasive Carcinoma), tissue source site International Genomics Consortium, specimen TCGA-AC-A2FK-01A (Primary Tumor).

[page 1 of 3]
SURGICAL PATHOLOGY REPORT

Patient Name: [REDACTED]
Med. Rec. #: [REDACTED]
DOB: [REDACTED]
Gender: [REDACTED]
Physician(s): [REDACTED]

Location: [REDACTED]
Service: [REDACTED]
Billing #: [REDACTED]

Accession #: [REDACTED]
Billing Type: [REDACTED]
Taken: [REDACTED]
Received: [REDACTED]
Reported: [REDACTED]

Specimen(s) Received

- A: Right breast tissue
- B: Sentinel node #1
- C: Sentinel node #2
- D: Left breast tissue
- E: Sentinel node #3

Pathologic Diagnosis

- A. **Right breast tissue, mastectomy:** Benign breast tissue with multiple intraductal papillomas and proliferative fibrocystic change.
- B. **Sentinel node #1:** One lymph node positive for metastatic lobular carcinoma. The deposit measures 1.6 cm in greatest dimension. Superficial extranodal extension is present.
- C. **Sentinel node #2:** One lymph node positive metastatic lobular carcinoma. The deposit measures 1.3 cm. Superficial extranodal extension is present.
- D. **Left breast tissue:**
Histologic Type: **Invasive lobular carcinoma**
Modified B-R Grade: **2**
Tumor Size: **Greatest dimension: 3.4 cm**
Additional dimensions: 3 X 1.2 cm
Margins of Invasive Carcinoma: **Negative**
Invasive carcinoma is located: 1.8 cm away from the deep margin
Lymphovascular Invasion: **Absent**
Ductal Carcinoma In Situ: **Absent**
Paget's Disease: **Absent**
Distant Metastasis: **Cannot be assessed**
Specimen Type: **Mastectomy**
Tumor Laterality: **Left**
Tumor Site: **Upper outer quadrant**
Lymph Node Sampling: **Sentinel lymph nodes only**
- ICD-0-3
carcinoma, infiltrating
lobular, NOS 8520/3
Site: breast, NOS C50.9
for 6/10/11*

[page 2 of 3]
[REDACTED]

Surgical Pathology Report

Comment: Small intraductal papillomas present. Hormone receptors were performed on previous specimen

E. Sentinel node #3: One lymph node positive for metastatic lobular carcinoma. The deposit measures 1.2 cm in greatest dimension. Superficial extranodal extension is present.

PATHOLOGIC STAGE: pT2, pNX, pMX

All three nodes sampled are positive and, therefore, the nodal stage is at least pN1a.

NOTE: Information on pathology stage and the operative procedure is transmitted to this Institution's Cancer Registry as required for accreditation by the Commission on Cancer. Pathology stage is based solely upon the current tissue specimen being evaluated and does not incorporate other relevant data. Pathology stage is only a component to be considered in determining the clinical stage and should not be confused with nor substituted for it. The exact operative procedure is available in the surgeon's operative report.

[REDACTED]

Clinical History

Breast carcinoma.

Gross Description

"A" - The specimen is received in formalin labeled "right breast". It consists of an unoriented mastectomy specimen without axillary tissue measuring 18 x 17.5 x 4 cm and weighing 719 grams. There is an overlying tan-white ellipse of skin measuring 12.2 x 9 cm showing a slightly eccentric, wrinkled pale tan areola, measuring 4.5 x 4.5 cm. In the center of the areola, there is an everted pale tan soft nipple measuring 1 x 1 x 0.5 cm. There are grossly no biopsy sites or healed incisions on the skin surface. The deep margin is inked black and the specimen is serially sectioned to reveal lobulated fat interspersed with a moderate amount soft-to-firm pink-tan nonfatty breast tissue. There are scattered pink-tan soft circumscribed nodules measuring up to 0.4 cm in diameter. Also noted are cysts filled with brown fluid measuring up to 0.3 cm in diameter. There is grossly no evidence of malignity. Representative sections are submitted in seven cassettes. Block summary: "A1" - vertical section of nipple; "A2" - cross section of nipple; "A3" - tissue underlying the nipple; "A4" - "A7" - tissue and nodules from each quadrant with the cyst included in cassette "4". The specimen is reviewed with

"B" - The specimen is received in formalin labeled "sentinel node #1". It consists of a firm pink-tan lymph node and attached fat measuring overall 1.5 x 1 x 0.2 cm. The specimen is bisected and totally submitted in cassette "B".

"C" - The specimen is received in formalin labeled "sentinel node #2". It consists of a pink-tan lymph node with attached fat measuring overall 1.3 x 0.8 x 0.6 cm. The specimen is bisected and totally submitted in cassette "C".

"D" - The specimen is received in formalin labeled "left breast". It consists of an unoriented mastectomy specimen without axillary tissue measuring 20 x 17 x 4 cm and weighing 744 grams. There is an overlying tan-white ellipse of skin measuring 11.5 x 8 cm showing a slightly eccentric, wrinkled pale tan areola, measuring 4.5 x 4.5 cm. In the center of the areola, there is an everted pale tan soft nipple measuring 1 x 1 x 0.5 cm. There are grossly no biopsy sites or healed incisions on the skin surface. However, a papule is identified 0.3 cm from the nearest margin of the skin ellipse, measuring 0.4 x 0.3 cm. The deep margin is inked black and the specimen is serially sectioned to reveal a firm pale pink-tan mass which appears to

[REDACTED]

[page 3 of 3]
Surgical Pathology Report

be within the upper outer quadrant measuring 3.4 x 3 x 1.2 cm. The mass comes to within 1.8 cm of the deep margin and 1 cm of the nearest superficial margin (inked blue). The mass comes to within 3.2 cm of the nipple. The deep margin is inked black and the specimen is serially sectioned to reveal lobulated fat interspersed with a moderate amount soft-to-firm pink-tan nonfatty breast tissue. The tumor shows adjacent linear and focal areas of induration extending predominantly lateral and medial. No lymph nodes are grossly identified at the axillary margin. Representative sections are submitted in 12 cassettes. Block summary: "D1" - vertical section of nipple; "D2" - cross section of nipple; "D3" - tumor and nearest superficial margin; "D4" - tumor and nearest deep margin; "D5" - tumor away from the surgical margin; "D6" and "D7" - irregular firm tissue approximately 1.5 cm medial to the tumor within the upper inner quadrant, "D8" and "D9" - irregularly firm tissue within the upper outer quadrant lateral to the tumor, "D10" - lower inner quadrant; "D11" - lower outer quadrant; "D12" - tissue underlying the nipple. The specimen is reviewed with

"E" - The specimen is received in formalin labeled "sentinel node #3". It consists of a tan-yellow portion of fatty tissue measuring 2 x 1.5 x 0.6 cm. Sectioning reveals a pink-tan lymph node measuring 1.7 x 0.6 x 0.4 cm. the lymph node is totally submitted in cassette "E".

Microscopic Description

Microscopic examination has been performed on all slides. The pathologic diagnosis encompasses the essential microscopic findings of this case.

Source: NCI Genomic Data Commons file dbedcbde-51c6-4b6d-a625-ffb92026ea1a (TCGA-AC-A2FK.1CF3FA64-EAE6-4A18-9B51-F5980A885371.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).